ALCHEMIST case ALCH-B3FG — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/3e0fc08f-bb64-4242-b5a7-022f8641b23c

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 64.8 years (23,658 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B3FG-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B3FG-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B3FG-TTP1-B-1-0-S1: Section location: Top; Percent tumor cells: 18; Percent tumor nuclei: 55; Percent normal cells: 68; Percent necrosis: 0; Percent stromal cells: 14; Percent lymphocyte infiltration: 34; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 1.
